Somatic mutation profile of tumor specimen TCGA-LP-A7HU-01A (aliquot TCGA-LP-A7HU-01A-11D-A33O-09) from TCGA case TCGA-LP-A7HU, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 53.6 years (19,595 days).
Specimen TCGA-LP-A7HU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 644ca12e-a893-4ccc-94d6-b796a15afbe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LP-A7HU-10A (Blood Derived Normal), aliquot TCGA-LP-A7HU-10A-01D-A33O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fc660e0-889c-48ec-8030-a2ece20eb1c2

The open-access MAF lists 184 somatic variants for this specimen: 125 protein-altering or splice-affecting, 54 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 54, Nonsense Mutation 10, Intron 3, Splice Site 3, In Frame Del 3, Frame Shift Del 2, 5'UTR 1, Splice Region 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 92/238 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 44/226 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ACVRL1 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1234976168, COSV66360118; called by muse, mutect2, varscan2
- ADAM12 | c.1005G>A p.M335I | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64106123; called by muse, mutect2, varscan2
- ADO | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.456); catalogued as COSV65677856; called by mutect2, varscan2
- AGBL5 | c.1775G>A p.W592* | Nonsense Mutation (SNP) | VAF 27/88 reads (31%) | catalogued as rs771699104, COSV59936482; called by muse, mutect2, varscan2
- AKAP12 | c.3776C>T p.S1259L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV53574544; called by muse, mutect2, varscan2
- ALDH1L1 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV56413681; called by muse, mutect2, varscan2
- ALK | c.3542G>A p.R1181H | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as rs1034835558, COSV66565306; ClinVar: uncertain significance; called by muse, mutect2
- ANAPC2 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1196966346, COSV60569850; called by muse, mutect2
- APOB | c.10945G>A p.E3649K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs754128155, COSV51934239; called by mutect2, varscan2
- ARFGAP2 | c.1417C>T p.H473Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV53565510; called by muse, mutect2, varscan2
- ARID1B | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as COSV51676564; called by muse, mutect2
- ARPP21 | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 18/99 reads (18%) | catalogued as COSV51797151; called by muse, mutect2, varscan2
- ASNSD1 | c.168G>T p.L56F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV53623627; called by muse, mutect2, varscan2
- ATAD5 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV58974315; called by muse, mutect2, varscan2
- ATAD5 | c.1437G>C p.K479N | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV58974330; called by muse, mutect2, varscan2
- ATP10A | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV63516940; called by muse, mutect2, varscan2
- C17orf75 | c.675G>C p.L225F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56752747; called by muse, mutect2, varscan2
- C20orf194 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV52695470; called by muse, mutect2
- CAPN3 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58821778; called by muse, mutect2, varscan2
- CCDC146 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs374413765; called by muse, varscan2
- CCR1 | c.1022C>G p.S341C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56122160; called by muse, mutect2, varscan2
- CEP120 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 20/122 reads (16%) | catalogued as COSV60265397; called by muse, mutect2, varscan2
- CEP250 | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV61169884; called by muse, mutect2, varscan2
- CFAP43 | c.3463G>A p.E1155K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63852982; called by muse, mutect2, varscan2
- CNTLN | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.036); catalogued as COSV52077150; called by muse, mutect2, varscan2
- CTRB2 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57315643; called by muse, mutect2, varscan2
- CUL9 | c.2407G>A p.V803I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs749941814, COSV52728152, COSV52734305; called by mutect2, varscan2
- CXCR3 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV101031753; called by muse, mutect2
- CXXC1 | c.1711G>C p.D571H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1340857249, COSV53274328; called by muse, mutect2
- CXXC1 | c.1414-1G>C p.X472_splice | Splice Site (SNP) | VAF 7/31 reads (23%) | catalogued as COSV53274337, COSV53274910; called by muse, mutect2, varscan2
- DCTD | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs778735165, COSV63866898; called by muse, mutect2, varscan2
- DLG5 | c.5585C>T p.T1862I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV64947850; called by muse, mutect2, varscan2
- DMXL2 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV51845729; called by muse, mutect2, varscan2
- EHD4 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.896); catalogued as rs747383299, COSV55004629; called by muse, mutect2, varscan2
- EHMT1 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 31/73 reads (42%) | catalogued as COSV58374635; called by muse, mutect2, varscan2
- FBN3 | c.6775C>G p.Q2259E | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.559); catalogued as COSV54459745, COSV54466378; called by muse, mutect2, varscan2
- FBXL14 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764480758, COSV59336282; called by muse, mutect2, varscan2
- FBXL15 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50045490; called by muse, mutect2, varscan2
- FERMT3 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1257489948, COSV54179295; called by muse, mutect2, varscan2
- FNBP4 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs1421571510, COSV55448335; called by muse, mutect2, varscan2
- FOXD4 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100071356; called by muse, mutect2
- FRY | c.4589C>T p.S1530L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV66569762; called by muse, mutect2, varscan2
- GABRD | c.1220C>A p.A407D | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as COSV66080497; called by muse, mutect2, varscan2
- GALNT13 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as COSV67219757; called by muse, mutect2, varscan2
- GLRA2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV54336084, COSV54349118; called by muse, mutect2, varscan2
- GPM6B | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as rs776965626, COSV57422321; called by muse, mutect2, varscan2
- GTPBP1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs774067054, COSV53284510; called by muse, mutect2, varscan2
- HAUS5 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as rs199586387; called by muse, mutect2, varscan2
- HESX1 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770886420, COSV55843058; called by muse, mutect2, varscan2
- HEYL | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV65721471, COSV65721608; called by muse, mutect2, varscan2
- HIVEP1 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.098); catalogued as COSV65101033; called by muse, mutect2
- IL22RA1 | c.556T>C p.Y186H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as COSV54628521; called by muse, mutect2, varscan2
- IQCN | c.3494C>A p.P1165Q | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV100828459; called by muse, mutect2
- JPT1 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs765086350, COSV59173331; called by muse, mutect2, varscan2
- JPT1 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100506826; called by muse, mutect2, varscan2
- KCNJ6 | c.765G>T p.L255F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55713779, COSV99898882; called by muse, mutect2, varscan2
- KRT35 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192328036; called by muse, mutect2, varscan2
- LAMC1 | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.864); catalogued as COSV51140513, COSV51151308; called by muse, mutect2, varscan2
- LEO1 | c.1033C>G p.Q345E | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV55174954, COSV55175672; called by muse, mutect2, varscan2
- MAGEA6 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.362); catalogued as COSV61448968; called by muse, mutect2, varscan2
- MAGEC3 | c.965A>T p.E322V | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.429); catalogued as COSV53579715; called by muse, mutect2, varscan2
- MAGEE2 | c.1102C>G p.L368V | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64897668; called by muse, mutect2, varscan2
- MAGI3 | c.3146G>A p.R1049H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779228525, COSV56834655; called by muse, mutect2, varscan2
- MCTP2 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV59143887; called by muse, mutect2, varscan2
- MINDY4 | c.1688G>A p.G563D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs561526056, COSV54673638; called by muse, mutect2, varscan2
- MOGS | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as rs747152213, COSV51968648; called by muse, mutect2, varscan2
- MRC2 | c.2187G>T p.K729N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); catalogued as rs1241893556, COSV100316865, COSV57639264; called by muse, varscan2
- MRTFB | c.939G>C p.Q313H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57957905; called by muse, mutect2
- MYC | c.830C>T p.S277L (on ENST00000377970; = p.S292L on NM_002467.6) | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as COSV52372044, COSV99421903; called by muse, mutect2
- MYOZ1 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV63771864; called by muse, mutect2, varscan2
- NCOR1 | c.5828C>T p.S1943L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs1189783787, COSV51973311, COSV51988699; called by muse, mutect2, varscan2
- OR52N1 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as rs1384449336, COSV57693310; called by muse, mutect2, varscan2
- PCDHB14 | c.428C>G p.S143* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV53388178; called by muse, mutect2, varscan2
- PCDHB14 | c.1156C>G p.Q386E | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); catalogued as COSV53388191, COSV53391539, COSV99505690; called by muse, mutect2, varscan2
- PCDHB4 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV52022084, COSV52023347; called by muse, mutect2, varscan2
- PGAP1 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV61325876; called by muse, mutect2, varscan2
- PNN | c.1704T>G p.N568K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.736); catalogued as COSV53766446, COSV99397157; called by muse, mutect2, varscan2
- PRL | c.204C>T p.F68= | Splice Region (SNP) | VAF 17/66 reads (26%) | catalogued as rs1328141274, COSV60591377; called by muse, mutect2, varscan2
- PRR23B | c.326A>G p.D109G | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.945); catalogued as COSV61493765; called by muse, mutect2, varscan2
- PSD | c.2965C>G p.P989A | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV50045475; called by muse, mutect2, varscan2
- PSG7 | c.738C>G p.I246M | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.888); catalogued as COSV101343268; called by muse, mutect2, varscan2
- PSMA1 | c.500C>G p.S167* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as COSV67165918; called by muse, mutect2, varscan2
- PTP4A3 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV61471632; called by muse, mutect2, varscan2
- PTPRU | c.3358C>G p.L1120V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60527356; called by muse, mutect2, varscan2
- RERG | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV57001069; called by muse, mutect2, varscan2
- ROBO2 | c.1438-1G>C p.X480_splice | Splice Site (SNP) | VAF 12/97 reads (12%) | catalogued as COSV100165509, COSV59909858; called by muse, mutect2, varscan2
- RUFY3 | c.877A>G p.T293A | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.956); catalogued as rs1197294462, COSV99888159; called by muse, mutect2
- SFTPA2 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs772763359, COSV64882452, COSV64882733; called by mutect2, varscan2
- SIGLEC8 | c.1148+1G>A p.X383_splice | Splice Site (SNP) | VAF 10/74 reads (14%) | catalogued as COSV58473593; called by muse, mutect2, varscan2
- SLC16A14 | c.1399A>G p.T467A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1031138671, COSV54618321; called by muse, mutect2, varscan2
- SLC22A25 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60595781; called by muse, mutect2, varscan2
- SOAT2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141707834; called by muse, mutect2, varscan2
- SP100 | c.2470A>G p.K824E | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.748); catalogued as rs1195649694, COSV50979303; called by muse, mutect2, varscan2
- STX8 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as rs550108459, COSV60490757; called by muse, mutect2, varscan2
- TASOR2 | c.5383G>C p.E1795Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV60167273; called by muse, mutect2, varscan2
- TMEM51 | c.458G>C p.R153T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV65690968; called by muse, mutect2, varscan2
- TP73 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60701106; called by muse, mutect2, varscan2
- TRIM41 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs769234157, COSV59318886; called by muse, mutect2, varscan2
- TTN | c.90788G>A p.R30263K (on ENST00000591111; = p.R22839K on NM_003319.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | PolyPhen benign (0.001); catalogued as COSV60034743; called by muse, mutect2
- TYR | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54474777; called by muse, mutect2, varscan2
- TYROBP | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.124); catalogued as COSV52887400; called by muse, mutect2, varscan2
- UBR2 | c.5113G>A p.D1705N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545959613, COSV65750021; called by muse, mutect2, varscan2
- UMODL1 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.018); catalogued as COSV68555720; called by muse, mutect2, varscan2
- UPF3B | c.440G>C p.R147T | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV52229927; called by muse, mutect2, varscan2
- USP34 | c.423G>C p.K141N | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.143); catalogued as COSV101277285; called by muse, mutect2, varscan2
- VGLL3 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs200777627, COSV67352349; called by muse, mutect2, varscan2
- WFDC2 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs757484769, COSV54151182, COSV54151769; called by muse, mutect2, varscan2
- XPNPEP2 | c.68C>A p.T23K | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs1390357648, COSV64367907; called by muse, mutect2, varscan2
- YIPF7 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV60656727, COSV60657595; called by muse, mutect2, varscan2
- ZC3H18 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as rs201777324, COSV99964551; called by muse, mutect2, varscan2
- ZNF20 | c.164T>C p.I55T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs1156821851, COSV100503199; called by muse, mutect2, varscan2
- ZNF208 | c.526A>G p.K176E | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.141); catalogued as COSV68104888; called by muse, mutect2, varscan2
- ZNF287 | c.1893G>T p.Q631H | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.961); catalogued as COSV101209453, COSV67688112; called by muse, mutect2
- ZNF335 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59817595; called by muse, mutect2, varscan2
- ZNF480 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 49/108 reads (45%) | catalogued as COSV57996047; called by muse, mutect2, varscan2
- ZNF619 | c.1587C>A p.N529K | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV59030035; called by muse, mutect2, varscan2
- BAG5 | c.136_137dup p.T47* | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- C15orf39 | c.2859_2873del p.Q954_A958del | In Frame Del (DEL) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- C2orf73 | c.627_628del p.K210Rfs*25 | Frame Shift Del (DEL) | VAF 30/73 reads (41%) | called by pindel, varscan2
- DCAF1 | c.1364C>G p.S455* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- DZIP1 | c.2027del p.T676Rfs*42 (on ENST00000347108; = p.T657Rfs*42 on NM_014934.5) | Frame Shift Del (DEL) | VAF 28/205 reads (14%) | called by mutect2, pindel, varscan2
- NOP9 | c.134_151del p.G45_P51delinsA | In Frame Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- RP1 | c.1681_1698del p.S561_L566del | In Frame Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- A2ML1 | c.3402C>T p.L1134= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV55285001, COSV55290232; called by muse, mutect2, varscan2
- AACS | c.816G>A p.P272= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs145117680; called by muse, mutect2, varscan2
- ACAD11 | c.1986G>A p.K662= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs754275847, COSV53895950, COSV53899098, COSV99391648; called by muse, varscan2
- AGO2 | c.1461C>A p.G487= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV55047158; called by muse, mutect2, varscan2
- ALG8 | c.24G>A p.T8= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as rs574242484, COSV55200282; called by muse, mutect2, varscan2
- ARHGEF10L | c.3564C>T p.L1188= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs768135814, COSV51432109; called by muse, mutect2
- ARHGEF15 | c.2109A>G p.G703= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV62725099; called by muse, mutect2
- ATAD5 | c.333G>A p.K111= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV58974297; called by muse, mutect2, varscan2
- ATP11A | c.903C>T p.L301= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs1431871196, COSV99370226; called by muse, mutect2, varscan2
- ATP8A2 | c.1617C>T p.G539= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV54950487; called by muse, mutect2, varscan2
- BAIAP2L2 | c.156C>T p.F52= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV59269554; called by muse, mutect2, varscan2
- BTBD16 | c.975C>T p.L325= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV53262765; called by muse, mutect2, varscan2
- BTBD7 | c.684A>G p.G228= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100108248; called by muse, mutect2, varscan2
- BTNL2 | c.768C>T p.L256= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs777649107, COSV66630660; called by muse, mutect2, varscan2
- C7 | c.2385G>A p.S795= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs751682564, COSV57473715; called by muse, mutect2, varscan2
- CACUL1 | c.528G>C p.S176= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV60994205, COSV60996122; called by muse, mutect2, varscan2
- CD300LF | c.693G>A p.Q231= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV56896895; called by muse, mutect2, varscan2
- CHRNA7 | c.1143C>T p.N381= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as rs542404300, COSV60967848; called by muse, mutect2, varscan2
- DIAPH3 | c.366C>T p.L122= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV57369723; called by muse, mutect2, varscan2
- DICER1 | c.1329C>T p.C443= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs776143079, COSV58619322; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF2B1 | c.381T>A p.T127= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV71194134; called by muse, mutect2, varscan2
- EPB41L1 | c.2286C>T p.S762= | Silent (SNP) | VAF 40/164 reads (24%) | catalogued as rs764008099, COSV52433006; called by muse, mutect2, varscan2
- GCC2 | c.90C>T p.L30= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs755657988, COSV59176079; called by muse, mutect2, varscan2
- GPR155 | c.543C>T p.N181= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as rs752106768, COSV55038806; called by muse, mutect2, varscan2
- HPCAL1 | c.315C>T p.F105= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV57146806; called by muse, mutect2
- HYDIN | c.13914G>A p.T4638= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs771353898; called by muse, mutect2, varscan2
- ICA1 | c.1451G>A p.*484= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV55578547; called by muse, mutect2, varscan2
- KIF27 | c.51C>T p.C17= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as COSV52827449; called by muse, mutect2, varscan2
- LHX1 | c.642G>A p.A214= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs775415590; called by muse, mutect2, varscan2
- LMAN2L | c.174G>A p.S58= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as rs1394736467, COSV53841621; called by muse, mutect2, varscan2
- LPO | c.777C>T p.I259= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV51858553; called by mutect2, varscan2
- NBPF1 | c.687C>T p.I229= | Silent (SNP) | VAF 38/732 reads (5%) | catalogued as COSV101236857; called by muse, mutect2
- PAF1 | c.663G>A p.V221= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV55393689; called by muse, varscan2
- PDP1 | c.706C>T p.L236= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs772866221, COSV52601432; called by muse, mutect2, varscan2
- PHC2 | c.753C>T p.A251= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs774326198, COSV57103670; called by muse, mutect2
- PIWIL3 | c.2463G>A p.T821= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs755057734, COSV59995258; called by muse, mutect2, varscan2
- PLA2G4F | c.657G>A p.L219= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as rs1260852083, COSV51826680; called by muse, mutect2, varscan2
- PLTP | c.519C>T p.T173= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV62464595; called by muse, mutect2, varscan2
- POMC | c.12G>A p.S4= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs773178150, COSV53034532; called by muse, mutect2, varscan2
- SCML1 | c.525C>T p.L175= (on ENST00000380041 / NM_001037540.3; = p.L148= on NM_006746.6) | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV66240376; called by muse, mutect2
- SELL | c.252G>A p.A84= (on ENST00000650983; = p.A71= on NM_000655.5) | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs750820001, COSV52550801; called by muse, mutect2, varscan2
- SFSWAP | c.915G>A p.K305= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV55521790; called by muse, mutect2, varscan2
- SLC13A2 | c.888G>A p.K296= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV58994745, COSV58994781; called by muse, mutect2, varscan2
- SLC18A1 | c.679C>A p.R227= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99368489, COSV99369007; called by muse, mutect2, varscan2
- SPOUT1 | c.195G>A p.E65= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV56913612, COSV56915761; called by muse, mutect2, varscan2
- TASOR2 | c.6303G>C p.V2101= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV60167287; called by muse, mutect2, varscan2
- TATDN2 | c.1263C>T p.P421= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV55051617; called by muse, mutect2, varscan2
- TLR5 | c.126C>G p.P42= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV60558876; called by muse, mutect2, varscan2
- TTN | c.65829C>T p.T21943= (on ENST00000591111; = p.T14519= on NM_003319.4) | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs761787250, COSV59960731; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBD1 | c.1293C>A p.I431= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV57872752; called by muse, mutect2, varscan2
- UTP14A | c.150C>T p.I50= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV64101400; called by muse, mutect2, varscan2
- XRN2 | c.1767G>A p.T589= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs138790989; called by muse, mutect2, varscan2
- ZFHX3 | c.2757C>T p.G919= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs141768802; called by muse, mutect2, varscan2
- ZIC1 | c.861C>T p.Y287= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV51553105, COSV51557963; called by muse, mutect2, varscan2
- AC244258.1 | n.855A>G | RNA (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- ATP5MD | c.-9-1831G>A | Intron (SNP) | VAF 22/90 reads (24%) | catalogued as COSV58915635; called by muse, varscan2
- MOB3C | c.-50-1641G>A | Intron (SNP) | VAF 12/67 reads (18%) | catalogued as COSV54719196; called by muse, mutect2, varscan2
- SKAP1 | c.978+6038G>A | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as COSV61146491; called by muse, mutect2, varscan2
- TTC27 | c.-1G>A | 5'UTR (SNP) | VAF 18/113 reads (16%) | catalogued as COSV100513694; called by muse, varscan2
